Somatic mutation profile of tumor specimen 0DM4XN from CCDI case PBCADR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.0 years (5,851 days).
Specimen 0DM4XN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3129bc51-1dc0-44ed-8178-52ce550d217f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM4X9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/417d4419-a1ea-4e83-af0d-944919bc6b07

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MRC1 | c.2663G>A p.G888D | Missense Mutation (SNP) | VAF 102/494 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.773); catalogued as rs1479890671; called by muse, varscan2
- ADGRB1 | c.3706+36C>T | Intron (SNP) | VAF 12/72 reads (17%) | catalogued as rs575575150; called by muse, varscan2
- CCDC114 | c.878-88C>T | Intron (SNP) | VAF 12/42 reads (29%) | called by muse, varscan2
- PDE8A | c.*85C>A | 3'UTR (SNP) | VAF 14/43 reads (33%) | called by muse, varscan2
